Somatic mutation profile of tumor specimen TARGET-20-PANDIX-04A (aliquot TARGET-20-PANDIX-04A-02D) from TARGET case TARGET-20-PANDIX, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 18.0 years (6,573 days).
Specimen TARGET-20-PANDIX-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 62258f95-1de8-47cb-a8c4-4f7582b99987.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANDIX-14A (Bone Marrow Normal), aliquot TARGET-20-PANDIX-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec89badb-40ed-4e9f-84c7-b42723a8b365

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CBL | c.1112A>C p.Y371S | Missense Mutation (SNP) | VAF 27/116 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs387906666, CM099545, COSV50633987, COSV50637098; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.215C>A p.A72D | Missense Mutation (SNP) | VAF 50/193 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen probably damaging (0.96); catalogued as rs121918454, CM013417, COSV61005613, COSV61008344, COSV61012146; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MKI67 | c.3041C>A p.P1014Q | Missense Mutation (SNP) | VAF 155/343 reads (45%) | SIFT tolerated (0.2); PolyPhen benign (0.188); catalogued as COSV64074519; called by muse, mutect2, varscan2
